Somatic mutation profile of tumor specimen TCGA-J8-A3O1-01A (aliquot TCGA-J8-A3O1-01A-11D-A21A-08) from TCGA case TCGA-J8-A3O1, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 33.2 years (12,113 days).
Specimen TCGA-J8-A3O1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 528bb111-b52e-451b-a33c-2e8e56eae7ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J8-A3O1-10A (Blood Derived Normal), aliquot TCGA-J8-A3O1-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cce456b-5c79-4a05-a824-6d33b3f7ffb7

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALCAM | c.470G>A p.C157Y | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60245471; called by muse, mutect2, varscan2
- CKAP2L | c.1316C>T p.T439I | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV56696508; called by muse, mutect2, varscan2
- LDHA | c.755T>C p.I252T | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.483); catalogued as COSV57040187; called by muse, mutect2
- LTF | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 100/236 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760436305, COSV51608007; called by muse, mutect2, varscan2
- MUC5AC | c.13783C>G p.P4595A | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated, low confidence (0.07); catalogued as rs1246197101, COSV100611509; called by muse, mutect2, varscan2
- MYH2 | c.3458G>T p.S1153I | Missense Mutation (SNP) | VAF 101/220 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55438248; called by muse, mutect2, varscan2
- PRKD1 | c.1148A>G p.Q383R | Missense Mutation (SNP) | VAF 134/281 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV59568947, COSV59590123; called by muse, mutect2, varscan2
- THAP5 | c.833C>T p.A278V (on ENST00000415914 / NM_001130475.3; = p.A236V on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV57950947; called by muse, mutect2
- TSFM | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs372337739; called by muse, mutect2, varscan2
- ZNF713 | c.557G>A p.R186K (on ENST00000633730 / NM_001366796.2; = p.R199K on NM_182633.3) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.1); catalogued as COSV70056822; called by muse, mutect2, varscan2
- CFAP65 | c.3045C>T p.V1015= | Silent (SNP) | VAF 84/254 reads (33%) | catalogued as COSV58560982; called by muse, mutect2, varscan2
- SRSF5 | c.447T>G p.V149= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV53682546; called by muse, mutect2, varscan2
